Somatic mutation profile of tumor specimen TARGET-10-PANWIM-09A (aliquot TARGET-10-PANWIM-09A-01D) from TARGET case TARGET-10-PANWIM, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.7 years (1,004 days).
Specimen TARGET-10-PANWIM-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6723293d-0234-4a36-ae43-8c3304bf1a38.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANWIM-14A (Bone Marrow Normal), aliquot TARGET-10-PANWIM-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9e6ebbad-be2b-49e1-a12a-bcd8855872f5

The open-access MAF lists 74 somatic variants for this specimen: 42 protein-altering or splice-affecting, 13 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 13, Intron 12, Nonsense Mutation 4, 3'UTR 3, 3'Flank 2, In Frame Ins 2, 5'UTR 2, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CSTF2 | c.262C>T p.R88* | Nonsense Mutation (SNP) | VAF 42/129 reads (33%) | catalogued as COSV63376166; called by muse, mutect2, varscan2
- DCAF4L2 | c.395G>C p.W132S | Missense Mutation (SNP) | VAF 32/248 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60480999; called by muse, mutect2, varscan2
- GABRG2 | c.842C>G p.S281* (on ENST00000361925 / NM_001375343.1; = p.S241* on NM_000816.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 9/265 reads (3%) | catalogued as COSV100729796; called by muse, mutect2
- ING3 | c.138C>G p.F46L | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.966); catalogued as COSV59242282, COSV59242844, COSV59243119; called by muse, mutect2
- MUC17 | c.10975C>T p.P3659S | Missense Mutation (SNP) | VAF 41/289 reads (14%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.599); catalogued as rs759475798, COSV60299252; called by muse, mutect2, varscan2
- NCOA6 | c.5549G>C p.G1850A | Missense Mutation (SNP) | VAF 26/173 reads (15%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.997); catalogued as rs746943519; called by muse, mutect2, varscan2
- PHF8 | c.1351G>A p.D451N (on ENST00000357988 / NM_001184896.1; = p.D415N on NM_015107.3) | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs1569527605, COSV100154186; called by muse, mutect2, varscan2
- SACS | c.2317C>T p.H773Y | Missense Mutation (SNP) | VAF 74/165 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as COSV66544867; called by muse, mutect2, varscan2
- SALL1 | c.1991C>T p.P664L | Missense Mutation (SNP) | VAF 55/139 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs74886565, COSV51764382; called by muse, mutect2, varscan2
- SEMA4C | c.1220G>A p.R407Q | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.029); catalogued as rs746995748; called by muse, mutect2, varscan2
- TJP3 | c.665C>T p.S222L | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.237); catalogued as rs375489474, COSV53663262; called by muse, mutect2, varscan2
- TNC | c.5156C>G p.S1719* | Nonsense Mutation (SNP) | VAF 5/96 reads (5%) | catalogued as COSV60787413; called by muse, mutect2
- ZNF713 | c.883C>T p.H295Y (on ENST00000633730 / NM_001366796.2; = p.H308Y on NM_182633.3) | Missense Mutation (SNP) | VAF 18/155 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV70057248; called by muse, mutect2, varscan2
- AGAP3 | c.1200_1201insGCC p.T400_Y401insA (on ENST00000622464; = p.T436_Y437insA on NM_031946.7 and 1 other RefSeq transcript) | In Frame Ins (INS) | VAF 9/36 reads (25%) | called by mutect2, pindel, varscan2
- ANGPTL5 | c.540+2T>A p.X180_splice | Splice Site (SNP) | VAF 28/130 reads (22%) | called by muse, mutect2, varscan2
- CAMTA2 | c.3454C>G p.L1152V | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.75); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- CBFA2T2 | c.991C>T p.Q331* | Nonsense Mutation (SNP) | VAF 35/234 reads (15%) | called by muse, mutect2, varscan2
- CCDC168 | c.12331G>A p.E4111K | Missense Mutation (SNP) | VAF 12/239 reads (5%) | SIFT tolerated (0.86); PolyPhen probably damaging (0.953); called by muse, mutect2
- CXCL14 | c.195G>C p.E65D (on ENST00000337225; = p.E53D on NM_004887.5) | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DLGAP3 | c.2107dup p.L703Pfs*13 | Frame Shift Ins (INS) | VAF 31/99 reads (31%) | called by pindel, varscan2
- HIVEP3 | c.5149G>C p.E1717Q | Missense Mutation (SNP) | VAF 8/206 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.476); called by muse, mutect2
- IGFL4 | c.359G>C p.R120T | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGHV1-69D | c.350_351insGGG | In Frame Ins (INS) | VAF 8/26 reads (31%) | called by mutect2, pindel
- KIF21A | c.1605T>G p.I535M | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MLIP | c.375C>G p.F125L | Missense Mutation (SNP) | VAF 18/302 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- NFKBIZ | c.1203C>G p.F401L | Missense Mutation (SNP) | VAF 24/208 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, varscan2
- NIPAL2 | c.652C>G p.L218V | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.484); called by muse, mutect2
- OR4F5 | c.523C>G p.P175A | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PARP4 | c.1574C>G p.P525R | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- PDXDC1 | c.1605G>C p.L535F | Missense Mutation (SNP) | VAF 6/156 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.423); called by muse, mutect2
- PLEKHM3 | c.853C>G p.Q285E | Missense Mutation (SNP) | VAF 7/174 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.038); called by muse, mutect2
- POLB | c.879C>G p.I293M | Missense Mutation (SNP) | VAF 30/163 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- PRRC1 | c.86C>G p.S29C | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- RNF103 | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 47/259 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SH3RF2 | c.1859C>G p.S620C | Missense Mutation (SNP) | VAF 13/135 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SPARCL1 | c.1238C>T p.S413L | Missense Mutation (SNP) | VAF 9/234 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.006); called by muse, mutect2
- STK38L | c.382G>C p.E128Q | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.367); called by muse, mutect2
- TENM2 | c.3154G>C p.E1052Q (on ENST00000518659 / NM_001122679.2; = p.E820Q on NM_001080428.3) | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TET1 | c.6076G>C p.E2026Q | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRAJ23 | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 21/136 reads (15%) | PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- VEPH1 | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.82); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZYG11A | c.1888G>C p.D630H | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.114); called by muse, mutect2
- ANK1 | c.2151G>A p.V717= | Silent (SNP) | VAF 6/60 reads (10%) | called by muse, mutect2, varscan2
- COL4A3 | c.435G>A p.G145= | Silent (SNP) | VAF 6/140 reads (4%) | catalogued as COSV67417181; called by muse, mutect2
- DDX18 | c.1278G>A p.K426= | Silent (SNP) | VAF 10/134 reads (7%) | called by muse, mutect2
- DNHD1 | c.11172C>G p.L3724= | Silent (SNP) | VAF 10/104 reads (10%) | called by muse, mutect2
- ENG | c.1599C>T p.L533= | Silent (SNP) | VAF 12/205 reads (6%) | called by muse, mutect2
- GALNT13 | c.1257G>A p.P419= | Silent (SNP) | VAF 64/182 reads (35%) | catalogued as rs752474364, COSV67210762, COSV67230656; called by muse, mutect2
- MYLK3 | c.1635C>T p.I545= | Silent (SNP) | VAF 5/84 reads (6%) | called by muse, mutect2
- PCMTD2 | c.384C>T p.F128= | Silent (SNP) | VAF 9/183 reads (5%) | called by muse, mutect2
- PDE3A | c.951G>A p.P317= | Silent (SNP) | VAF 13/95 reads (14%) | called by muse, mutect2, varscan2
- SCN1A | c.4443C>A p.V1481= (on ENST00000303395 / NM_001202435.3; = p.V1470= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/54 reads (9%) | catalogued as COSV57689145; called by muse, mutect2
- SOAT2 | c.540G>A p.A180= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as rs1476633603; called by muse, mutect2, varscan2
- THADA | c.4296G>A p.L1432= | Silent (SNP) | VAF 71/182 reads (39%) | called by muse, mutect2, varscan2
- TTN | c.87582G>A p.K29194= (on ENST00000591111; = p.K21770= on NM_003319.4) | Silent (SNP) | VAF 27/177 reads (15%) | called by muse, mutect2, varscan2
- ACAT2 | c.634+108C>G | Intron (SNP) | VAF 4/21 reads (19%) | called by muse, mutect2, varscan2
- AK9 | c.3633+13_3633+15del | Intron (DEL) | VAF 6/32 reads (19%) | catalogued as rs201441562; called by pindel, varscan2
- AL590143.1 | chr6:84688735 G>C | 3'Flank (SNP) | VAF 10/84 reads (12%) | called by muse, mutect2, varscan2
- CCDC57 | c.777-64C>T | Intron (SNP) | VAF 14/192 reads (7%) | called by muse, mutect2
- CFAP57 | c.3010-410C>T | Intron (SNP) | VAF 25/67 reads (37%) | catalogued as rs1239155390; called by muse, mutect2, varscan2
- FAM149B1 | c.*21C>G | 3'UTR (SNP) | VAF 8/94 reads (9%) | called by muse, mutect2
- FAM20C | c.864-17739G>A | Intron (SNP) | VAF 9/119 reads (8%) | called by muse, mutect2
- FAM32EP | chr12:126458004 A>C | 3'Flank (SNP) | VAF 19/30 reads (63%) | called by muse, mutect2, varscan2
- HIF1A | c.-48G>C | 5'UTR (SNP) | VAF 12/81 reads (15%) | catalogued as rs1463612679; called by muse, mutect2, varscan2
- IDS | c.419-1073T>C | Intron (SNP) | VAF 30/72 reads (42%) | catalogued as COSV61711348; called by muse, mutect2, varscan2
- IGLV1-44 | c.-84C>T | 5'UTR (SNP) | VAF 7/62 reads (11%) | called by muse, mutect2
- MDM4 | c.343+41G>C | Intron (SNP) | VAF 37/234 reads (16%) | called by muse, mutect2, varscan2
- NEIL1 | c.-23+461C>T | Intron (SNP) | VAF 6/42 reads (14%) | called by mutect2, varscan2
- NOX4 | c.1516-121G>C | Intron (SNP) | VAF 22/44 reads (50%) | called by muse, mutect2, varscan2
- PCDH10 | c.*76C>T | 3'UTR (SNP) | VAF 12/264 reads (5%) | called by muse, mutect2
- TMEM14C | c.*49C>G | 3'UTR (SNP) | VAF 56/128 reads (44%) | catalogued as COSV99994540; called by muse, mutect2, varscan2
- UBXN11 | c.852+12C>T | Intron (SNP) | VAF 5/32 reads (16%) | catalogued as rs1246565033; called by muse, mutect2, varscan2
- UQCC2 | c.284-131C>G | Intron (SNP) | VAF 9/32 reads (28%) | called by muse, mutect2, varscan2
- XKR4 | c.806+58209G>A | Intron (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2
